Somatic mutation profile of tumor specimen TCGA-LN-A49V-01A (aliquot TCGA-LN-A49V-01A-11D-A247-09) from TCGA case TCGA-LN-A49V, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,922 days).
Specimen TCGA-LN-A49V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d15892f-0cf5-4b4e-be36-9a1b957e9996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49V-10A (Blood Derived Normal), aliquot TCGA-LN-A49V-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a29ce17-9851-4c81-bb50-8102dc0fa7c6

The open-access MAF lists 114 somatic variants for this specimen: 79 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 33, Nonsense Mutation 4, Splice Site 4, In Frame Del 2, Intron 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.133C>T p.R45* (on ENST00000399959; = p.R46* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs1569234653, CM158020, COSV101302319; ClinVar: pathogenic; called by muse, varscan2
- EP300 | c.4617+1G>A p.X1539_splice | Splice Site (SNP) | VAF 28/31 reads (90%) | hotspot (GDC flag); catalogued as COSV54326069, COSV54327425; called by muse, mutect2, varscan2
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 36/36 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARMC4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs148908705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1C2 | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55359656; called by muse, mutect2, varscan2
- ATPAF2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs778802460, COSV58263245; called by muse, mutect2, varscan2
- BIN2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.744); catalogued as COSV53329279; called by muse, mutect2, varscan2
- C3 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1443451793, COSV55570277; called by muse, mutect2, varscan2
- C8G | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs754194146; called by muse, mutect2, varscan2
- CACNB1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746197912; called by muse, mutect2, varscan2
- CCDC71 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58909742; called by muse, mutect2, varscan2
- CELSR2 | c.8564G>A p.R2855Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs1344384359, COSV54780657; called by muse, varscan2
- CLIP2 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1352937677, COSV56286082; called by muse, mutect2, varscan2
- DIAPH1 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99525844; called by muse, mutect2, varscan2
- GALNT18 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.526); catalogued as rs529247669; called by muse, mutect2, varscan2
- KIR3DL2 | c.1328G>T p.C443F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.992); catalogued as rs1352715600; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2, varscan2
- MAN2B2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750214368; called by muse, mutect2, varscan2
- NFKB2 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs747113965; called by muse, varscan2
- NOTCH1 | c.4582T>C p.C1528R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53029190; called by muse, mutect2, varscan2
- NTRK3 | c.2477C>T p.A826V (on ENST00000360948 / NM_001012338.2; = p.A812V on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs1299718659, COSV62307818, COSV62311911; called by muse, mutect2, varscan2
- OPN4 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1482166886, COSV54117067; called by muse, mutect2, varscan2
- OR4A16 | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1443363362; called by muse, mutect2, varscan2
- OR51F2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV59063949, COSV59064687; called by muse, mutect2, varscan2
- PCDHB7 | c.2240A>G p.Y747C | Missense Mutation (SNP) | VAF 68/73 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99175405; called by muse, mutect2, varscan2
- PLEKHM2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1331611746; called by muse, mutect2
- PRAG1 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as rs375344955, COSV58163858; called by muse, mutect2, varscan2
- RNLS | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760004178, COSV100076386; called by muse, mutect2, varscan2
- SLC16A13 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs766655813; called by muse, mutect2, varscan2
- SULF1 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs745984464, COSV52693165; called by muse, mutect2, varscan2
- TCF3 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as rs867551757, COSV53645513; called by muse, mutect2, varscan2
- TENM3 | c.2924T>A p.F975Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69321335; called by muse, mutect2, varscan2
- TENT4A | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs748296365, COSV50094534; called by muse, mutect2, varscan2
- UBQLN1 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs1017176011; called by muse, mutect2, varscan2
- ZBTB2 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as COSV57311733; called by muse, mutect2, varscan2
- ZFAT | c.1084_1086del p.K362del | In Frame Del (DEL) | VAF 10/81 reads (12%) | catalogued as rs767616893; called by pindel, varscan2
- ABCF2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by mutect2, varscan2
- AKAP12 | c.4012G>A p.V1338I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ALB | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATRNL1 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL18A1 | c.2047_2065del p.A683Sfs*35 (on ENST00000359759 / NM_130444.3; = p.A448Sfs*35 on NM_030582.4) | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel
- CRY1 | c.1240T>C p.C414R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2
- DNTTIP1 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- DYSF | c.3800C>A p.S1267* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- EHBP1 | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- EIF3E | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ELAC2 | c.1743del p.N582Tfs*23 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- FAM71A | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FHOD1 | c.2834T>C p.I945T | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GABRE | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- GMPPA | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IMPG1 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- JAKMIP3 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KALRN | c.5101G>C p.V1701L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KIFBP | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- LAMA2 | c.2857-8_2865del p.X953_splice | Splice Site (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- MAGI1 | c.1233_1235dup p.Q421dup | In Frame Ins (INS) | VAF 14/48 reads (29%) | called by pindel, varscan2
- MBLAC1 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM4 | c.1175-17_1195del p.X392_splice | Splice Site (DEL) | VAF 12/135 reads (9%) | called by mutect2, pindel
- METTL27 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGRN1 | c.562-1G>A p.X188_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- NPAS2 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF3L1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | called by muse, mutect2, varscan2
- PCDH8 | c.2972C>T p.T991M | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLCB3 | c.3325G>T p.A1109S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- POU6F1 | c.1451C>A p.A484E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2
- QRSL1 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RAB3GAP2 | c.981_983del p.L327_S328delinsF | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- SLC4A1AP | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SLIT2 | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX7 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SUPT20HL1 | c.2600T>C p.V867A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD1 | c.3233T>G p.F1078C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TDRD9 | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2
- TOP1MT | c.1326dup p.R443Afs*9 | Frame Shift Ins (INS) | VAF 36/72 reads (50%) | called by mutect2, pindel, varscan2
- TRAC | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TRIM17 | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC13C | c.691A>C p.S231R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- YARS2 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGTPBP1 | c.321C>A p.T107= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100429327; called by muse, mutect2
- ALOX5 | c.504C>A p.I168= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs766792732; called by muse, mutect2, varscan2
- ANKRD16 | c.996G>A p.K332= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1230382898, COSV51948295; called by muse, mutect2, varscan2
- BCL9 | c.3744G>A p.T1248= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs782211226; called by muse, mutect2, varscan2
- C10orf82 | c.213C>T p.S71= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs374577819; called by muse, mutect2, varscan2
- C4orf50 | c.153G>A p.E51= (on ENST00000324058; = p.E1283= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CA8 | c.780A>G p.A260= | Silent (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- CEP170B | c.4251C>T p.D1417= (on ENST00000453495; = p.D1346= on NM_015005.3) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs768674837, COSV99229857; called by muse, mutect2, varscan2
- DMXL1 | c.8001G>C p.L2667= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- DUSP8 | c.279G>A p.T93= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs141702492, COSV100524438; called by muse, mutect2, varscan2
- DYNC2I1 | c.1290T>C p.I430= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FLG2 | c.6C>T p.T2= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1390172532, COSV101166280, COSV66170253; called by muse, mutect2
- ISL2 | c.564G>A p.T188= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs748397463; called by muse, mutect2, varscan2
- ITGB2 | c.846C>T p.N282= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs767870813, CM120017, COSV56608165; called by muse, mutect2, varscan2
- LMOD1 | c.111C>T p.D37= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs774692839; called by muse, mutect2, varscan2
- LTBP2 | c.3660C>T p.D1220= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs764055325; called by muse, mutect2
- MDC1 | c.5373G>A p.V1791= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1468722360; called by muse, mutect2, varscan2
- MMP17 | c.1608G>A p.V536= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- NPR1 | c.1245C>T p.P415= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs201584708, COSV100903724; called by muse, mutect2, varscan2
- OR51G2 | c.618T>C p.F206= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- PHF20 | c.1902G>A p.V634= | Silent (SNP) | VAF 61/86 reads (71%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.402C>T p.S134= (on ENST00000394691; = p.S190= on NM_001308147.2) | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs776854734, COSV55977690; called by muse, mutect2, varscan2
- POLR2H | c.405C>T p.F135= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs776845280, COSV99201219; called by muse, mutect2, varscan2
- PRRC2B | c.729C>G p.S243= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- RCN3 | c.123C>T p.S41= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as rs745347733; called by muse, mutect2, varscan2
- REXO1 | c.2118G>A p.A706= | Silent (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- RMND1 | c.1035T>A p.S345= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- RUNX1T1 | c.717C>T p.N239= (on ENST00000265814 / NM_001198628.1; = p.N212= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/79 reads (63%) | catalogued as rs187368715; called by muse, mutect2, varscan2
- SCUBE1 | c.2841C>T p.F947= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs375344449; called by muse, mutect2, varscan2
- SHE | c.552C>T p.P184= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100496028; called by muse, mutect2, varscan2
- SLC35F5 | c.849C>T p.I283= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1265507611; called by muse, mutect2
- SPRYD3 | c.1299C>T p.V433= | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- VPS18 | c.1257C>T p.P419= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs778725367; called by muse, mutect2, varscan2
- ASIC2 | c.556-179605G>C | Intron (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 6/76 reads (8%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2
